Somatic mutation profile of tumor specimen 0DJVPL from CCDI case PBBWYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,897 days).
Specimen 0DJVPL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87f9a460-b026-4a91-ad09-289550b8d4ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVP7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5674d93a-4588-43ff-ade7-4461201eb564

The open-access MAF lists 60 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Intron 8, Nonsense Mutation 4, 3'UTR 4, Frame Shift Del 2, In Frame Del 1, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADORA2A | c.616C>G p.R206G | Missense Mutation (SNP) | VAF 322/1545 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV58379187; called by muse, mutect2, varscan2
- BCOR | c.4009G>T p.E1337* (on ENST00000378444 / NM_001123385.2; = p.E1303* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 568/700 reads (81%) | catalogued as COSV100653088, COSV60720521; called by muse, mutect2, varscan2
- BHLHE22 | c.221_260del p.G74Afs*18 | Frame Shift Del (DEL) | VAF 128/960 reads (13%) | catalogued as rs778657494; called by mutect2, pindel
- CTNNA3 | c.1674C>G p.Y558* | Nonsense Mutation (SNP) | VAF 352/1580 reads (22%) | catalogued as COSV65608795; called by muse, mutect2, varscan2
- EXTL3 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 429/1836 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs756747852; called by muse, mutect2, varscan2
- FCAMR | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 228/1222 reads (19%) | catalogued as COSV61367570; called by muse, mutect2, varscan2
- GRM6 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 357/843 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); catalogued as COSV51443617; called by muse, mutect2, varscan2
- ITGBL1 | c.1313C>A p.A438D | Missense Mutation (SNP) | VAF 365/1007 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV66008298; called by muse, mutect2, varscan2
- NEU2 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 96/1134 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.012); catalogued as rs1294256408, COSV52091852; called by muse, mutect2
- PSG8 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 90/918 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.564); catalogued as rs536270387; called by muse, mutect2
- SYNPO2L | c.1585G>A p.A529T (on ENST00000394810 / NM_001114133.3; = p.A305T on NM_024875.5) | Missense Mutation (SNP) | VAF 172/548 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1417956814; called by muse, mutect2, varscan2
- TACR3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 110/620 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs538867830; called by muse, mutect2, varscan2
- TNS3 | c.3268G>A p.V1090M | Missense Mutation (SNP) | VAF 109/688 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1401825753; called by muse, mutect2, varscan2
- YTHDC2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 275/1097 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1456391474; called by muse, mutect2, varscan2
- ZNF799 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 360/1132 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756554232, COSV70122336; called by muse, mutect2, varscan2
- ABCG8 | c.348_377del p.D116_K126delinsE | In Frame Del (DEL) | VAF 107/812 reads (13%) | called by mutect2, pindel, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 50/1959 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC170 | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 402/1029 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CHIT1 | c.68A>T p.K23I | Missense Mutation (SNP) | VAF 74/876 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2
- CS | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 444/1912 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOC2 | c.2201A>C p.E734A | Missense Mutation (SNP) | VAF 258/1504 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- FGFR2 | c.454+8A>G | Splice Region (SNP) | VAF 161/1182 reads (14%) | called by muse, mutect2, varscan2
- GP1BA | c.1845_1849delinsATT p.N616Lfs*30 | Frame Shift Del (DEL) | VAF 229/671 reads (34%) | called by pindel, varscan2*
- KDR | c.2971+2T>C p.X991_splice | Splice Site (SNP) | VAF 136/869 reads (16%) | called by muse, mutect2, varscan2
- KIAA1143 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 261/715 reads (37%) | called by mutect2, varscan2
- MALRD1 | c.44A>C p.E15A | Missense Mutation (SNP) | VAF 164/1741 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.058); called by muse, mutect2
- OR5P3 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 302/1103 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by mutect2, varscan2
- OR8G2P | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 407/1745 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PAPSS2 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 196/896 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PECAM1 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 357/1243 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SEPTIN8 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 136/2087 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.133); called by muse, mutect2
- TMEM191B | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 122/2284 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TNRC6A | c.3085G>A p.G1029S | Missense Mutation (SNP) | VAF 175/962 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5A | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 86/1538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS9D1 | c.765G>C p.W255C | Missense Mutation (SNP) | VAF 183/524 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- BIRC3 | c.774C>T p.R258= | Silent (SNP) | VAF 98/1620 reads (6%) | called by muse, mutect2
- CABS1 | c.876C>T p.T292= | Silent (SNP) | VAF 361/899 reads (40%) | catalogued as rs1378046698, COSV56733941; called by muse, mutect2, varscan2
- CCDC7 | c.2526G>T p.V842= | Silent (SNP) | VAF 376/1278 reads (29%) | called by muse, mutect2, varscan2
- EXTL1 | c.1314G>A p.A438= | Silent (SNP) | VAF 98/587 reads (17%) | catalogued as rs369796783; called by muse, mutect2, varscan2
- GSTT4 | c.426C>T p.N142= | Silent (SNP) | VAF 133/3073 reads (4%) | called by muse, mutect2
- IL7R | c.1245G>T p.L415= | Silent (SNP) | VAF 222/1000 reads (22%) | catalogued as rs547350466; called by muse, mutect2, varscan2
- NSUN2 | c.1089G>A p.Q363= | Silent (SNP) | VAF 148/1566 reads (9%) | called by muse, mutect2
- PAX5 | c.621G>A p.P207= | Silent (SNP) | VAF 121/718 reads (17%) | catalogued as rs774759102, COSV100814643; called by muse, mutect2, varscan2
- PDE1B | c.285G>A p.S95= | Silent (SNP) | VAF 348/1434 reads (24%) | called by muse, mutect2, varscan2
- RAI14 | c.2127G>T p.V709= | Silent (SNP) | VAF 414/1611 reads (26%) | called by muse, mutect2, varscan2
- TARS1 | c.2100C>A p.T700= | Silent (SNP) | VAF 204/2497 reads (8%) | called by muse, mutect2
- TRIM37 | c.2766C>A p.G922= | Silent (SNP) | VAF 431/977 reads (44%) | catalogued as COSV51889736; called by muse, mutect2, varscan2
- AP001267.5 | c.*239del | 3'UTR (DEL) | VAF 45/407 reads (11%) | catalogued as rs375905420, COSV63281755, COSV63293331; called by pindel, varscan2
- CHERP | c.*89C>T | 3'UTR (SNP) | VAF 91/244 reads (37%) | catalogued as rs1329133116; called by muse, mutect2, varscan2
- CREBBP | c.3837-19C>T | Intron (SNP) | VAF 163/398 reads (41%) | catalogued as rs1327492843; called by muse, mutect2, varscan2
- ELP4 | c.1147-19922T>A | Intron (SNP) | VAF 386/1346 reads (29%) | called by mutect2, varscan2
- ETAA1 | c.*27A>G | 3'UTR (SNP) | VAF 24/728 reads (3%) | catalogued as rs895226065; called by muse, mutect2
- FARP2 | c.1893+1768_1893+1775del | Intron (DEL) | VAF 181/825 reads (22%) | called by mutect2, pindel, varscan2
- FKBP1B | c.199-43G>T | Intron (SNP) | VAF 305/1056 reads (29%) | called by muse, mutect2, varscan2
- GCA | c.306+45G>T | Intron (SNP) | VAF 117/344 reads (34%) | called by muse, mutect2, varscan2
- ILVBL | c.1721-63G>T | Intron (SNP) | VAF 121/395 reads (31%) | called by muse, mutect2, varscan2
- MCF2 | c.1490+69G>A | Intron (SNP) | VAF 66/169 reads (39%) | called by muse, mutect2, varscan2
- NECTIN2 | c.1042+3779G>A | Intron (SNP) | VAF 238/1760 reads (14%) | catalogued as rs559949569; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/293 reads (10%) | called by muse, varscan2
- TGFBI | c.*9A>T | 3'UTR (SNP) | VAF 152/1632 reads (9%) | called by muse, mutect2
